Somatic mutation profile of tumor specimen C3N-02440-02 (aliquot CPT0384430009) from CPTAC case C3N-02440, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.5 years (23,940 days).
Specimen C3N-02440-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa008926-5562-4f9e-b467-acbdc55d3f9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02440-31 (Blood Derived Normal), aliquot CPT0385420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bb1c9ee-310b-4347-928f-e6dc2ab0bc1d

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSBG1 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs772359349, COSV51906138; called by muse, mutect2, varscan2
- KIF26A | c.3163G>A p.A1055T | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.321); catalogued as COSV100181589; called by muse, mutect2, varscan2
- PRKN | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 99/588 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.619); catalogued as rs1042122187; called by muse, mutect2, varscan2
- C16orf87 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CCDC74B | c.849G>T p.W283C | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP77 | c.116C>A p.A39E | Missense Mutation (SNP) | VAF 71/430 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- CFAP94 | c.1891A>G p.T631A (on ENST00000320267 / NM_001352064.2; = p.T637A on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX36 | c.525A>T p.E175D | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRG2B | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 77/586 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IFT81 | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); called by muse, mutect2
- MTCL1 | c.3626T>A p.L1209* (on ENST00000306329 / NM_001378206.1; = p.L890* on NM_015210.4) | Nonsense Mutation (SNP) | VAF 48/234 reads (21%) | called by muse, mutect2, varscan2
- OGDH | c.751A>C p.K251Q | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- RAD54L2 | c.2474T>C p.L825P | Missense Mutation (SNP) | VAF 74/296 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UMODL1 | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC009779.3 | c.33C>T p.S11= | Silent (SNP) | VAF 39/199 reads (20%) | catalogued as rs1297319654; called by muse, mutect2
- CTNND2 | c.1818C>A p.T606= | Silent (SNP) | VAF 81/436 reads (19%) | called by muse, mutect2, varscan2
- VN1R4 | c.387T>C p.F129= | Silent (SNP) | VAF 18/262 reads (7%) | catalogued as rs1408099906; called by muse, mutect2
- ZNF334 | c.1950C>T p.H650= | Silent (SNP) | VAF 44/261 reads (17%) | called by muse, mutect2, varscan2
- MAPRE3 | c.267+149C>T | Intron (SNP) | VAF 6/42 reads (14%) | catalogued as rs746749532; called by muse, varscan2
- PLCB1 | c.3423+2377C>T | Intron (SNP) | VAF 8/136 reads (6%) | called by muse, mutect2
